Gene-level copy-number profile of tumor specimen ALCH-B4C8-TTP1-A from ALCHEMIST case ALCH-B4C8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.2 years (25,291 days).
Specimen ALCH-B4C8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d550851d-ea87-4e6b-8863-ce479f781df0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4C8-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/2e054cbe-1541-4312-a022-65c10131e05d

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 506; copy number 1: 28,505; copy number 2: 24,055; copy number 3: 4,744; copy number 4: 934; copy number 5: 139; copy number 6: 10; copy number 7: 2; copy number 8: 1; copy number 12: 2.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr2:185,956,587–186,422,432, 3 genes (within-gene range 0–1): RPL21P32, LINC01473, AC104058.1.
- chr4:151,027,090–151,027,617, 1 gene: AK4P6.
- chr6:107,065,182–107,115,515, 1 gene: BEND3.
- chr7:63,011,463–63,011,569, 1 gene: RNU6-417P.
- chr9:21,367,424–22,214,672, 32 genes: IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:39,886,861–39,892,895, 3 genes: RN7SL763P, SNORA70, CR769767.1.
- chr9:39,983,821–39,984,401, 1 gene: RPL7AP49.
- chr9:64,810,865–64,836,341, 2 genes: BNIP3P4, AL359955.1.
- chr10:11,611,305–11,764,070, 3 genes (within-gene range 0–1): AL512631.2, AL512631.1, ECHDC3.
- chr19:36,687,612–36,727,701, 1 gene (within-gene range 0–1): ZNF567.
- chr21:7,744,962–10,649,835, 69 genes (broad region; genes not listed).
- chr22:18,970,439–19,031,242, 7 genes: DGCR5, AC007326.3, DGCR5, AC007326.1, AC000095.2, AC000095.1, FAM246C.
- chr22:21,383,374–21,396,590, 4 genes: RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 5,832 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–3,955,262, 210 genes, copy number 3 (broad region; genes not listed).
- chr1:100,331,804–100,542,021, 6 genes, copy number 3: AC104457.1, AC104457.2, CDC14A, BCAS2P2, AL589990.1, GPR88.
- chr2:37,562,486–38,231,651, 13 genes, copy number 3 (within-gene range 2–3): AC006369.1, CDC42EP3, AC006369.2, AC010878.1, LINC00211, RMDN2, RMDN2-AS1, CYP1B1, CYP1B1-AS1, AC009229.4, AC009229.2, RNU6-951P, AC009229.3.
- chr2:97,083,583–102,028,544, 93 genes, copy number 3–4 (broad region; genes not listed).
- chr2:209,424,058–211,299,189, 19 genes, copy number 3: MAP2, RNA5SP118, UNC80, SNAI1P1, RPE, KANSL1L, AC007038.1, KANSL1L-AS1, RPL6P6, AC006994.1, ACADL, Y_RNA, MYL1, LANCL1-AS1, LANCL1, CPS1, CPS1-IT1, AC012491.1, RPS27P10.
- chr3:53,797,764–54,058,864, 8 genes, copy number 3: AC012467.1, CHDH, IL17RB, AC012467.2, ACTR8, SELENOK, AC115282.2, CABYRP1.
- chr3:88,338,416–90,261,708, 13 genes, copy number 3: CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:118,900,557–121,660,927, 71 genes, copy number 3–5 (broad region; genes not listed).
- chr3:123,490,820–124,953,819, 23 genes, copy number 3: HACD2, MYLK-AS1, MYLK, MYLK-AS2, AC020634.2, AC020634.1, CCDC14, ROPN1, KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13.
- chr3:136,808,551–176,114,537, 584 genes, copy number 4–6 (broad region; genes not listed).
- chr4:67,417,305–68,129,869, 24 genes, copy number 3: AC104806.2, RNU1-63P, RNA5SP527, AC104806.1, CENPC, STAP1, AC096720.2, UBA6, AC096720.1, UBA6-AS1, ST3GAL1P1, AC079880.1, AC079880.2, GNRHR, SNORA62, TMPRSS11CP, TMPRSS11D, TMPRSS11A, TMPRSS11GP, RNU6-95P, GCOM2, MTND2P41, TMPRSS11F, SYT14P1.
- chr4:68,537,184–68,670,652, 5 genes, copy number 3: UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:24,772,144–45,895,970, 295 genes, copy number 3 (broad region; genes not listed).
- chr6:29,708,125–31,478,936, 148 genes, copy number 3–4 (broad region; genes not listed).
- chr6:31,528,962–31,558,829, 8 genes, copy number 3: MCCD1, DDX39B, ATP6V1G2-DDX39B, SNORD117, SNORD84, DDX39B-AS1, ATP6V1G2, NFKBIL1.
- chr7:79,452,877–97,437,896, 210 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr7:98,989,867–99,877,057, 37 genes, copy number 3 (within-gene range 2–3): AC004893.2, RNF14P3, SMURF1, AC004893.1, KPNA7, MYH16, AC004834.1, AC004922.1, ARPC1A, ARPC1B, PDAP1, BUD31, PTCD1, ATP5MF-PTCD1, CPSF4, AC073063.1, ATP5MF, ZNF789, ZNF394, ZKSCAN5, FAM200A, ZNF655, AC005020.2, TMEM225B, ZSCAN25, AC005020.1, CYP3A5, CYP3A7-CYP3A51P, CYP3A51P, CYP3A7, CYP3A4, AC069294.1, CYP3A137P, CYP3A43, AC011904.1, CYP3A52P, OR2AE1.
- chr8:46,549,089–49,076,093, 58 genes, copy number 3: HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL.
- chr8:67,849,044–97,277,928, 435 genes, copy number 3 (broad region; genes not listed).
- chr8:144,098,633–144,118,328, 3 genes, copy number 4: SHARPIN, MAF1, WDR97.
- chr10:45,706,431–47,002,488, 41 genes, copy number 3: FAM21FP, AL645998.1, WASHC2C, AC012044.1, FAM25E, AGAP4, PARGP1, RNA5SP310, RPL35AP23, TIMM23, SNORA74C-1, NCOA4, MSMB, RPL23AP61, AGAP7P, ANTXRLP1, ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20.
- chr11:92,913,227–96,514,748, 99 genes, copy number 3 (broad region; genes not listed).
- chr11:100,641,975–135,075,908, 730 genes, copy number 3 (broad region; genes not listed).
- chr12:53,708,517–53,898,976, 4 genes, copy number 3–4 (within-gene range 2–4): CALCOCO1, AC076968.2, CISTR, AC076968.1.
- chr12:85,318,060–104,350,307, 325 genes, copy number 3–4 (broad region; genes not listed).
- chr12:105,704,203–109,110,992, 71 genes, copy number 3 (broad region; genes not listed).
- chr12:113,422,380–113,789,807, 5 genes, copy number 3–4 (within-gene range 2–4): SDSL, LHX5, LHX5-AS1, LINC01234, DYNLL1P4.
- chr14:54,396,849–93,116,320, 724 genes, copy number 3 (within-gene range 2–4) (broad region; genes not listed).
- chr14:93,138,066–102,911,500, 324 genes, copy number 3 (broad region; genes not listed).
- chr14:103,241,492–106,879,812, 291 genes, copy number 3–4 (within-gene range 3–6) (broad region; genes not listed).
- chr15:72,398,302–72,900,260, 20 genes, copy number 5: TMEM202, TMEM202-AS1, PHBP20, AC079322.1, ARIH1, MIR630, AC100827.3, AC100827.5, AC100827.2, LINC02259, AC100827.4, AC100827.1, GOLGA6B, RN7SL853P, HIGD2B, AC009712.1, BBS4, ADPGK, ADPGK-AS1, NPM1P42.
- chr16:64,735,925–65,234,914, 6 genes, copy number 3 (within-gene range 2–3): PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2.
- chr16:77,657,174–77,743,000, 3 genes, copy number 3: AC092724.1, NUDT7, AC092134.1.
- chr16:78,014,683–78,066,761, 4 genes, copy number 3: AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr19:41,449,520–44,500,524, 148 genes, copy number 3 (broad region; genes not listed).
- chr20:87,250–17,609,919, 320 genes, copy number 3–4 (broad region; genes not listed).
- chr20:18,113,467–26,251,546, 199 genes, copy number 3 (broad region; genes not listed).
- chr21:40,863,994–46,691,226, 210 genes, copy number 3 (broad region; genes not listed).
- chr22:21,103,016–21,371,945, 17 genes, copy number 3: BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, AP000552.1.
- chr22:25,434,324–25,520,854, 6 genes, copy number 4: AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Autosomal genes at a single copy (total copy number 1): 26,239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
